Gene-level copy-number profile of tumor specimen TARGET-20-PASIEP-09A from TARGET case TARGET-20-PASIEP, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.7 years (6,082 days).
Specimen TARGET-20-PASIEP-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.86825ade-faa9-5494-8409-5add517b9fc9.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PASIEP-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate.
https://portal.gdc.cancer.gov/files/1945c1ae-0f42-43c4-901f-d9ec0cbfe37c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,384; copy number 2: 57,840; copy number 3: 20; copy number 4: 27; copy number 14: 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:1,561,385–1,620,061, 2 genes, copy number 14 (within-gene range 2–14): SIRPB1, AL049634.3.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
